Somatic mutation profile of tumor specimen 0DEHQ5 from CCDI case PBBPXA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, metastatic, NOS; Tissue or organ of origin: Lateral wall of nasopharynx; Age at diagnosis: 16.5 years (6,016 days).
Specimen 0DEHQ5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c992629f-a6e9-442b-b2c2-b6921cf55d85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEHN4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8703e154-66d3-4b45-9b23-b296134384a6

The open-access MAF lists 31 somatic variants for this specimen: 16 protein-altering or splice-affecting, 9 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 9, Intron 4, Frame Shift Del 2, 3'UTR 2, Nonsense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP99 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 104/513 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs1047053192; called by muse, mutect2, varscan2
- EBF4 | c.1541-4G>A | Splice Region (SNP) | VAF 62/247 reads (25%) | catalogued as rs1385394912; called by muse, mutect2, varscan2
- H2BC5 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.16); catalogued as COSV56800630, COSV56801968; called by muse, mutect2, varscan2
- SELENON | c.1575G>A p.M525I | Missense Mutation (SNP) | VAF 62/384 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1057515466; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTC7B | c.690C>A p.F230L | Missense Mutation (SNP) | VAF 35/223 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.878); catalogued as COSV60629201; called by muse, mutect2, varscan2
- VPS53 | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 27/430 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1210022180; called by muse, mutect2
- COPB1 | c.1950G>T p.E650D | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2
- ICE1 | c.4622_4623del p.Y1541Lfs*2 | Frame Shift Del (DEL) | VAF 79/456 reads (17%) | called by pindel, varscan2
- KMT2D | c.11170C>T p.Q3724* | Nonsense Mutation (SNP) | VAF 85/353 reads (24%) | called by muse, mutect2, varscan2
- LCE3B | c.176G>C p.R59T | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); called by muse, mutect2
- MAP3K19 | c.1373G>A p.G458D | Missense Mutation (SNP) | VAF 106/485 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ME3 | c.164G>A p.R55K | Missense Mutation (SNP) | VAF 90/385 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NELL2 | c.2001T>A p.N667K | Missense Mutation (SNP) | VAF 9/217 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- RECQL5 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 57/264 reads (22%) | called by muse, mutect2, varscan2
- SBNO2 | c.3382_3383del p.S1128Wfs*25 | Frame Shift Del (DEL) | VAF 62/272 reads (23%) | called by pindel, varscan2
- SLC26A7 | c.1017T>G p.D339E | Missense Mutation (SNP) | VAF 58/277 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAMLG | c.228C>T p.L76= | Silent (SNP) | VAF 98/462 reads (21%) | catalogued as rs987834942; called by muse, mutect2, varscan2
- CSMD1 | c.5517G>A p.S1839= (on ENST00000520002; = p.S1838= on NM_033225.6) | Silent (SNP) | VAF 96/487 reads (20%) | catalogued as rs541557117, COSV100145522, COSV100153121; called by muse, mutect2, varscan2
- ETV1 | c.162G>A p.Q54= | Silent (SNP) | VAF 98/399 reads (25%) | called by muse, mutect2, varscan2
- FAM133A | c.258C>T p.S86= | Silent (SNP) | VAF 111/285 reads (39%) | called by muse, mutect2, varscan2
- LRRC58 | c.463C>T p.L155= | Silent (SNP) | VAF 67/405 reads (17%) | catalogued as COSV55231031; called by muse, mutect2, varscan2
- OR9G1 | c.567C>T p.G189= | Silent (SNP) | VAF 112/886 reads (13%) | catalogued as rs770442188, COSV56448164; called by muse, varscan2
- PXMP4 | c.330C>T p.L110= | Silent (SNP) | VAF 38/471 reads (8%) | catalogued as COSV54133980; called by muse, mutect2
- RAPGEF3 | c.2214C>T p.F738= (on ENST00000389212; = p.F696= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/600 reads (3%) | called by muse, mutect2
- TLNRD1 | c.792C>T p.F264= | Silent (SNP) | VAF 14/220 reads (6%) | catalogued as rs1002817227; called by muse, mutect2
- BACE2 | c.312+11037C>T | Intron (SNP) | VAF 61/305 reads (20%) | catalogued as rs778853538, COSV57737180; called by muse, mutect2, varscan2
- CRY1 | c.1657+19A>G | Intron (SNP) | VAF 41/201 reads (20%) | called by muse, mutect2, varscan2
- GPC5 | c.*44C>T | 3'UTR (SNP) | VAF 33/150 reads (22%) | catalogued as COSV100993127; called by muse, mutect2, varscan2
- IPO11 | c.1021+11T>C | Intron (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- IZUMO1 | c.235+34C>A | Intron (SNP) | VAF 24/95 reads (25%) | called by muse, mutect2, varscan2
- LRIT2 | c.*89T>C | 3'UTR (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
